Somatic mutation profile of tumor specimen TCGA-BP-5201-01A (aliquot TCGA-BP-5201-01A-01D-1429-08) from TCGA case TCGA-BP-5201, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.3 years (23,125 days).
Specimen TCGA-BP-5201-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f19d3a-a03f-4b5b-b5c6-68a576aceff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5201-11A (Solid Tissue Normal), aliquot TCGA-BP-5201-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07d87e8e-10a4-46bb-b876-6c0bb69767bb

The open-access MAF lists 42 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 6, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 125/233 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs765175940, COSV53065226; called by muse, mutect2, varscan2
- ADAM33 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV62936846; called by muse, mutect2, varscan2
- ALMS1 | c.7114A>C p.M2372L | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV52521463; called by muse, mutect2, varscan2
- ARCN1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV50617555; called by muse, mutect2, varscan2
- BMPR1B | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52781607; called by muse, mutect2, varscan2
- BOC | c.1906A>C p.I636L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV56357532; called by muse, mutect2, varscan2
- CDT1 | c.739T>G p.Y247D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56349815; called by muse, mutect2, varscan2
- DYNC1H1 | c.8972C>A p.A2991E | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV64142117; called by muse, mutect2
- ELP2 | c.1270T>G p.S424A | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV60854332; called by muse, mutect2, varscan2
- GUCY2C | c.1703C>G p.S568C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53795255, COSV99663462; called by muse, mutect2
- IDE | c.1825T>C p.Y609H | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56427202; called by muse, mutect2, varscan2
- KRT31 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1429741232, COSV52438478; called by muse, mutect2, varscan2
- LAMA1 | c.5963G>A p.R1988K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67544094; called by muse, mutect2
- LNPEP | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781635777, COSV51481243; called by muse, mutect2, varscan2
- LONP1 | c.1636C>G p.R546G | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62261355, COSV62263284; called by muse, mutect2, varscan2
- MTF1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 46/121 reads (38%) | catalogued as COSV65962954; called by muse, mutect2, varscan2
- MTIF2 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 17/484 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55054035; called by muse, mutect2
- NOL6 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV53045481; called by muse, mutect2, varscan2
- PGAM2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs1300195215; called by muse, varscan2
- PHF12 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.607); catalogued as COSV52022006; called by muse, mutect2, varscan2
- PHF20L1 | c.2165T>C p.I722T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV55197864; called by muse, mutect2, varscan2
- RAI1 | c.3850G>A p.G1284S | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as COSV55398844; called by muse, mutect2
- RALGAPB | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.989); catalogued as COSV53443917; called by muse, mutect2, varscan2
- RGS22 | c.2741A>C p.K914T | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV62667263; called by muse, mutect2, varscan2
- SMIM8 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57641241; called by muse, mutect2, varscan2
- SNTG1 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52470817; called by muse, mutect2, varscan2
- TCTEX1D2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs748477420, COSV57487827, COSV57489367; called by muse, mutect2, varscan2
- TMPO | c.1743G>T p.Q581H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs746562573, COSV54125155; called by muse, mutect2, varscan2
- TXNIP | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as rs782036651, COSV65221392; called by muse, mutect2, varscan2
- VAT1 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV55896956; called by muse, mutect2, varscan2
- HCFC2 | c.783dup p.G262Wfs*6 | Frame Shift Ins (INS) | VAF 60/185 reads (32%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4045del p.L1349Wfs*35 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- RMND5A | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by mutect2, varscan2
- ZNF800 | c.1290dup p.L431Ifs*9 | Frame Shift Ins (INS) | VAF 73/246 reads (30%) | called by mutect2, pindel, varscan2
- GON4L | c.4794G>T p.R1598= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV55203540; called by muse, mutect2, varscan2
- KDM6A | c.2076G>A p.Q692= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV65045427; called by muse, mutect2, varscan2
- PRSS55 | c.843C>G p.T281= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV60808999, COSV60809323; called by muse, mutect2
- SAMD9L | c.1812A>G p.L604= | Silent (SNP) | VAF 139/360 reads (39%) | catalogued as COSV59085063; called by muse, mutect2, varscan2
- SLC44A3 | c.900C>A p.V300= (on ENST00000271227 / NM_001114106.3; = p.V252= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/239 reads (5%) | catalogued as COSV54733805; called by muse, mutect2
- TUBB4B | c.738C>A p.L246= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs151064868; called by muse, mutect2, varscan2
- EIF4A1 | c.515-117T>A | Intron (SNP) | VAF 21/73 reads (29%) | catalogued as COSV51512255; called by muse, mutect2, varscan2
